Somatic mutation profile of tumor specimen TCGA-68-8251-01A (aliquot TCGA-68-8251-01A-11D-2293-08) from TCGA case TCGA-68-8251, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 78.7 years (28,739 days).
Specimen TCGA-68-8251-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a3ee443d-a8df-48b0-9ecb-37dfc51cdb8c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-68-8251-10A (Blood Derived Normal), aliquot TCGA-68-8251-10A-01D-2293-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b96af673-d58d-41b1-801f-dfb36624eb63

The open-access MAF lists 315 somatic variants for this specimen: 239 protein-altering or splice-affecting, 72 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 211, Silent 72, Nonsense Mutation 14, Frame Shift Del 7, Splice Site 4, Intron 2, Splice Region 2, Frame Shift Ins 1, RNA 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACAD9 | c.235A>C p.T79P | Missense Mutation (SNP) | VAF 35/270 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.202); catalogued as COSV100459036; called by muse, mutect2, varscan2
- ACBD4 | c.247G>C p.E83Q | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.285); catalogued as COSV58850784; called by muse, mutect2, varscan2
- ACSBG1 | c.123G>C p.L41F | Missense Mutation (SNP) | VAF 130/503 reads (26%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0); catalogued as COSV99357182; called by muse, mutect2, varscan2
- AIRE | c.1384G>A p.G462S | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs540790785; called by muse, mutect2, varscan2
- AKR1E2 | c.902G>A p.R301Q | Missense Mutation (SNP) | VAF 60/139 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs761904189, COSV53632042; called by muse, mutect2, varscan2
- AMPD3 | c.1403G>A p.R468H (on ENST00000396553 / NM_001025389.2; = p.R477H on NM_000480.3) | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs753026219, COSV101158119, COSV67332311; called by muse, mutect2, varscan2
- ANGPT1 | c.1211A>G p.Y404C | Missense Mutation (SNP) | VAF 25/105 reads (24%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.926); catalogued as COSV99862364; called by muse, mutect2, varscan2
- APLP1 | c.772G>A p.V258M | Missense Mutation (SNP) | VAF 111/396 reads (28%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.843); catalogued as rs752536466, COSV99697592; called by muse, mutect2, varscan2
- ARID4B | c.2896G>C p.E966Q | Missense Mutation (SNP) | VAF 60/217 reads (28%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.272); catalogued as COSV99935267; called by muse, mutect2, varscan2
- ATG9B | c.643G>T p.D215Y | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.122); catalogued as COSV99874072; called by muse, mutect2, varscan2
- ATP10D | c.2617G>C p.E873Q | Missense Mutation (SNP) | VAF 50/207 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.192); catalogued as COSV99904918, COSV99905362; called by muse, mutect2, varscan2
- ATP2A3 | c.1597C>T p.R533C | Missense Mutation (SNP) | VAF 40/90 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.141); catalogued as rs772480917, COSV99988957; called by muse, mutect2, varscan2
- ATP2B1 | c.1090G>A p.G364R | Missense Mutation (SNP) | VAF 23/129 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99665386; called by muse, mutect2, varscan2
- BANK1 | c.1255G>T p.D419Y | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); catalogued as rs893222221, COSV100536056; called by muse, mutect2, varscan2
- BCAR3 | c.1883G>A p.S628N | Missense Mutation (SNP) | VAF 24/228 reads (11%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs1385494560, COSV99550480; called by muse, mutect2, varscan2
- BCL10 | c.222A>C p.E74D | Missense Mutation (SNP) | VAF 37/215 reads (17%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.932); catalogued as COSV100997772; called by muse, mutect2, varscan2
- BCR | c.3361G>A p.V1121M | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); catalogued as rs745984288, COSV100006196; called by muse, mutect2, varscan2
- BNC2 | c.2633G>A p.R878Q | Missense Mutation (SNP) | VAF 43/121 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1180035312, COSV66146216; called by muse, mutect2, varscan2
- BNC2 | c.2038G>T p.E680* | Nonsense Mutation (SNP) | VAF 27/73 reads (37%) | catalogued as COSV101032570, COSV101032941, COSV66152042; called by muse, mutect2, varscan2
- C5 | c.3737G>A p.R1246H | Missense Mutation (SNP) | VAF 46/141 reads (33%) | SIFT tolerated (0.47); PolyPhen benign (0.005); catalogued as rs142569129; called by muse, mutect2, varscan2
- CACNA1E | c.4999G>C p.E1667Q | Missense Mutation (SNP) | VAF 28/127 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100701619; called by muse, mutect2, varscan2
- CASP8 | c.326C>T p.S109L (on ENST00000432109 / NM_033355.3; = p.S141L on NM_001228.4) | Missense Mutation (SNP) | VAF 36/150 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as COSV51845577, COSV51845735; called by muse, mutect2, varscan2
- CASQ1 | c.334G>C p.E112Q | Missense Mutation (SNP) | VAF 84/371 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.112); catalogued as rs979091500, COSV100927256, COSV100927337; called by muse, mutect2, varscan2
- CASQ2 | c.47C>G p.S16C | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.01); catalogued as COSV99797231; called by muse, mutect2, varscan2
- CC2D1A | c.2106C>G p.I702M | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.903); catalogued as rs926148895, COSV100528356; called by muse, mutect2, varscan2
- CCDC40 | c.3397G>A p.A1133T | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as rs1219930549, COSV100163040; called by muse, mutect2, varscan2
- CD101 | c.2606G>T p.G869V | Missense Mutation (SNP) | VAF 23/159 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99869329; called by muse, mutect2, varscan2
- CD72 | c.721C>T p.Q241* | Nonsense Mutation (SNP) | VAF 34/115 reads (30%) | catalogued as COSV52409777, COSV99427343; called by muse, mutect2, varscan2
- CDC40 | c.1101A>G p.I367M | Missense Mutation (SNP) | VAF 37/123 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.792); catalogued as COSV100309200; called by muse, mutect2, varscan2
- CDCA7L | c.1067G>A p.C356Y | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100178249; called by muse, mutect2, varscan2
- CDH19 | c.2029G>C p.E677Q | Missense Mutation (SNP) | VAF 64/245 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.119); catalogued as COSV100051038, COSV100051218; called by muse, mutect2, varscan2
- CDK15 | c.476C>G p.A159G (on ENST00000652192 / NM_001366386.2; = p.A108G on NM_139158.2) | Missense Mutation (SNP) | VAF 70/265 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99642894; called by muse, mutect2, varscan2
- CDRT1 | c.1805T>A p.V602E | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.058); catalogued as COSV100599806; called by muse, mutect2, varscan2
- CGN | c.2030G>A p.R677Q | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as rs144821285; called by muse, mutect2, varscan2
- CHD2 | c.2443C>G p.Q815E | Missense Mutation (SNP) | VAF 45/204 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101244926; called by muse, mutect2, varscan2
- CLCNKB | c.574G>C p.E192Q | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.364); catalogued as COSV100990215; called by muse, varscan2
- CLIP2 | c.953C>G p.S318C | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99791228; called by muse, mutect2, varscan2
- COL6A3 | c.5797T>G p.Y1933D | Missense Mutation (SNP) | VAF 17/124 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV99796911; called by muse, mutect2, varscan2
- COPA | c.2773C>T p.Q925* | Nonsense Mutation (SNP) | VAF 42/203 reads (21%) | catalogued as COSV99615035; called by muse, varscan2
- CPAMD8 | c.3136G>A p.E1046K (on ENST00000651564; = p.E999K on NM_015692.5) | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs775573426, COSV101488447; called by muse, mutect2, varscan2
- CPXM2 | c.1399G>T p.E467* | Nonsense Mutation (SNP) | VAF 33/98 reads (34%) | catalogued as COSV99581475; called by muse, mutect2, varscan2
- CR1 | c.3637C>G p.Q1213E | Missense Mutation (SNP) | VAF 67/339 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.109); catalogued as COSV100887468; called by muse, mutect2, varscan2
- CRYBG3 | c.6888G>A p.K2296= | Splice Region (SNP) | VAF 12/62 reads (19%) | catalogued as COSV99476768; called by muse, mutect2, varscan2
- CRYGS | c.473G>C p.R158P | Missense Mutation (SNP) | VAF 28/179 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.191); catalogued as COSV100329942; called by muse, mutect2, varscan2
- CUX2 | c.3338C>A p.P1113H | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99919106; called by muse, mutect2, varscan2
- CYGB | c.484G>A p.V162M | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.2); catalogued as rs762689341, COSV99505996; called by muse, mutect2, varscan2
- CYP26A1 | c.1204C>A p.H402N | Missense Mutation (SNP) | VAF 47/136 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV99814623; called by muse, mutect2, varscan2
- DDX19B | c.200G>T p.R67I | Missense Mutation (SNP) | VAF 152/410 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV99849869; called by muse, mutect2, varscan2
- DENND2A | c.1139A>T p.E380V | Missense Mutation (SNP) | VAF 62/249 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99325780; called by muse, mutect2, varscan2
- DGAT2 | c.119G>A p.W40* | Nonsense Mutation (SNP) | VAF 14/69 reads (20%) | catalogued as rs750549977, COSV99929620; called by muse, varscan2
- DGCR2 | c.112C>T p.R38C | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.79); catalogued as rs751483287, COSV54216745; called by muse, mutect2, varscan2
- DGKH | c.1612G>A p.V538I | Missense Mutation (SNP) | VAF 34/130 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.012); catalogued as rs201754211; called by muse, mutect2, varscan2
- DHX15 | c.1196G>A p.R399H | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs754378482, COSV61027175; called by muse, mutect2, varscan2
- DNAJC10 | c.1815A>T p.L605F | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.961); catalogued as COSV99899032; called by muse, mutect2, varscan2
- DRG2 | c.596C>T p.S199L | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.124); catalogued as rs151078395; called by muse, mutect2, varscan2
- DSG1 | c.2456G>T p.G819V | Missense Mutation (SNP) | VAF 44/293 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.143); catalogued as COSV57138486, COSV99935668, COSV99935741; called by muse, mutect2, varscan2
- DYSF | c.4826A>G p.K1609R | Missense Mutation (SNP) | VAF 37/166 reads (22%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.595); catalogued as COSV99245468; called by muse, mutect2, varscan2
- ECM1 | c.967C>T p.R323C | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs148594423; called by muse, mutect2, varscan2
- EFCC1 | c.1738C>T p.P580S | Missense Mutation (SNP) | VAF 17/148 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs1160956856, COSV101459969; called by muse, mutect2, varscan2
- EIF3A | c.2705G>A p.G902E | Missense Mutation (SNP) | VAF 12/201 reads (6%) | SIFT tolerated (0.36); PolyPhen benign (0.031); catalogued as COSV100974546; called by muse, mutect2
- EIF6 | c.305C>T p.S102L | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55773001; called by muse, mutect2, varscan2
- ELOF1 | c.29C>T p.P10L | Missense Mutation (SNP) | VAF 44/159 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.516); catalogued as rs943633264, COSV99370608; called by muse, mutect2, varscan2
- EMC2 | c.424C>T p.R142W | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.897); catalogued as rs536838549, COSV99624003; called by muse, mutect2, varscan2
- ERICH1 | c.802G>C p.D268H | Missense Mutation (SNP) | VAF 81/283 reads (29%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.966); catalogued as COSV100032256; called by muse, mutect2, varscan2
- ESX1 | c.725C>T p.P242L | Missense Mutation (SNP) | VAF 71/160 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV65424475; called by muse, mutect2, varscan2
- EYA4 | c.1729G>T p.E577* (on ENST00000531901 / NM_001301013.1; = p.E571* on NM_004100.5) | Nonsense Mutation (SNP) | VAF 50/224 reads (22%) | catalogued as COSV100765485; called by muse, mutect2, varscan2
- F3 | c.421G>A p.G141R | Missense Mutation (SNP) | VAF 23/163 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs759484806, COSV100474256; called by muse, mutect2, varscan2
- F5 | c.3637C>T p.L1213F | Missense Mutation (SNP) | VAF 128/496 reads (26%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.005); catalogued as COSV100889007, COSV63123636; called by muse, mutect2, varscan2
- FAT1 | c.11230C>G p.P3744A | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.997); catalogued as COSV101499173; called by muse, mutect2, varscan2
- FAT3 | c.8339A>G p.H2780R | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.026); catalogued as COSV99963707; called by muse, mutect2, varscan2
- FBLN5 | c.871G>A p.E291K | Missense Mutation (SNP) | VAF 45/124 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99969451; called by muse, mutect2, varscan2
- FBXO11 | c.1511G>A p.G504E (on ENST00000403359 / NM_001190274.2; = p.G420E on NM_025133.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100319236; called by muse, mutect2, varscan2
- FCRL3 | c.907G>C p.E303Q | Missense Mutation (SNP) | VAF 63/281 reads (22%) | SIFT tolerated (0.33); PolyPhen benign (0.101); catalogued as COSV100943006; called by muse, mutect2, varscan2
- FIP1L1 | c.256G>A p.D86N | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV100184308; called by muse, mutect2, varscan2
- FYCO1 | c.1531C>G p.L511V | Missense Mutation (SNP) | VAF 8/209 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); catalogued as COSV56117537, COSV99945373; called by muse, mutect2
- GIMAP6 | c.603C>A p.N201K | Missense Mutation (SNP) | VAF 48/348 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100188146; called by muse, mutect2, varscan2
- GIMAP8 | c.1789C>T p.R597* | Nonsense Mutation (SNP) | VAF 58/203 reads (29%) | catalogued as rs200127471, COSV100217422; called by muse, mutect2, varscan2
- GMPS | c.832C>T p.R278* | Nonsense Mutation (SNP) | VAF 14/73 reads (19%) | catalogued as COSV99903001; called by muse, mutect2, varscan2
- GON4L | c.2697G>C p.E899D | Missense Mutation (SNP) | VAF 31/147 reads (21%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.99); catalogued as COSV99673788; called by muse, mutect2, varscan2
- GRIA3 | c.1678G>C p.V560L | Missense Mutation (SNP) | VAF 73/343 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.97); catalogued as COSV52074777, COSV99989481; called by muse, mutect2, varscan2
- HAL | c.1325G>T p.G442V | Missense Mutation (SNP) | VAF 56/185 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1449387256, COSV99701295; called by muse, mutect2, varscan2
- HGF | c.371A>G p.Y124C | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99736193; called by muse, mutect2
- HOXB13 | c.8C>A p.P3H | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.343); catalogued as COSV99285139; called by muse, mutect2, varscan2
- HSD17B7 | c.493C>G p.Q165E | Missense Mutation (SNP) | VAF 22/127 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.174); catalogued as COSV99597647; called by muse, mutect2, varscan2
- HSPA2 | c.1415G>A p.R472H | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.93); catalogued as COSV55969892; called by muse, mutect2, varscan2
- IFT122 | c.3554G>A p.R1185Q (on ENST00000348417 / NM_052989.3; = p.R1126Q on NM_018262.4) | Missense Mutation (SNP) | VAF 72/175 reads (41%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.978); catalogued as rs754808589, COSV56210209; called by muse, mutect2, varscan2
- IGKV1D-8 | c.348C>A p.F116L | Missense Mutation (SNP) | VAF 28/253 reads (11%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs748154211; called by muse, mutect2, varscan2
- IGKV6D-21 | c.128G>A p.R43Q | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as rs746479477; called by mutect2, varscan2
- IGSF10 | c.7824G>C p.K2608N | Missense Mutation (SNP) | VAF 73/379 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.841); catalogued as COSV99177228; called by muse, mutect2, varscan2
- IGSF9 | c.2345C>G p.S782C (on ENST00000368094 / NM_001135050.2; = p.S766C on NM_020789.4) | Missense Mutation (SNP) | VAF 28/133 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.41); catalogued as COSV100231020; called by muse, mutect2, varscan2
- IL17REL | c.161C>T p.T54M | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.653); catalogued as rs376895359, COSV58008359; called by muse, mutect2, varscan2
- INSR | c.1911G>C p.Q637H | Missense Mutation (SNP) | VAF 108/394 reads (27%) | SIFT tolerated (0.42); PolyPhen benign (0.067); catalogued as COSV100251778; called by muse, mutect2, varscan2
- IQGAP2 | c.323G>A p.R108Q | Missense Mutation (SNP) | VAF 41/129 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs764865648, COSV57171272; called by muse, mutect2, varscan2
- IRF4 | c.286C>A p.R96S | Missense Mutation (SNP) | VAF 106/232 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV101110804, COSV66704417; called by muse, mutect2, varscan2
- ITGB8 | c.211G>C p.E71Q | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.752); catalogued as rs1562668741, COSV99750955; called by muse, mutect2, varscan2
- KBTBD11 | c.1429C>T p.R477C | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as rs144532869; called by muse, varscan2
- KCTD5 | c.18C>A p.C6* | Nonsense Mutation (SNP) | VAF 8/16 reads (50%) | catalogued as COSV100069504; called by muse, mutect2, varscan2
- KDM4C | c.1199T>A p.V400D | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV101184719; called by muse, mutect2, varscan2
- KDM7A | c.1616T>C p.L539S | Missense Mutation (SNP) | VAF 37/238 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99134090; called by muse, mutect2, varscan2
- KIF16B | c.1696-1G>C p.X566_splice | Splice Site (SNP) | VAF 5/35 reads (14%) | catalogued as COSV100734013; called by muse, mutect2, varscan2
- KIF1B | c.1856G>A p.R619H (on ENST00000377086 / NM_001365952.1; = p.R573H on NM_015074.3) | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.961); catalogued as rs202061430, COSV99822862; called by muse, mutect2, varscan2
- KNTC1 | c.197C>T p.S66L | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as COSV100338091, COSV100338694; called by muse, mutect2, varscan2
- KRT12 | c.691G>A p.D231N | Missense Mutation (SNP) | VAF 49/173 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs1318203783, COSV99288851; called by muse, mutect2, varscan2
- KRT77 | c.1330C>T p.R444W | Missense Mutation (SNP) | VAF 25/123 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs199965086, COSV100526977; called by muse, mutect2, varscan2
- KRTAP19-3 | c.133G>T p.G45* | Nonsense Mutation (SNP) | VAF 65/468 reads (14%) | catalogued as COSV100477476, COSV61855299; called by muse, mutect2, varscan2
- LDLR | c.2398G>A p.V800I | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs200243555, COSV99369726; ClinVar: not provided; called by muse, mutect2, varscan2
- LILRB4 | c.692C>A p.S231Y | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.725); catalogued as COSV99553636; called by muse, mutect2, varscan2
- LIN7B | c.616C>G p.R206G | Missense Mutation (SNP) | VAF 95/456 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.4); catalogued as COSV55522088; called by muse, mutect2, varscan2
- LSM4 | c.326G>T p.R109L | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.931); catalogued as COSV99416878; called by muse, mutect2, varscan2
- LY75 | c.1402G>A p.E468K | Missense Mutation (SNP) | VAF 49/171 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99716197; called by muse, mutect2, varscan2
- MAP2 | c.1761G>T p.E587D | Missense Mutation (SNP) | VAF 21/151 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.038); catalogued as COSV99558848; called by muse, mutect2, varscan2
- MATR3 | c.2332G>A p.E778K | Missense Mutation (SNP) | VAF 38/115 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.074); catalogued as COSV100735138; called by muse, mutect2, varscan2
- MCM2 | c.88C>T p.R30* | Nonsense Mutation (SNP) | VAF 70/337 reads (21%) | catalogued as rs1181496683, COSV99412948; called by muse, mutect2, varscan2
- MGA | c.7222G>C p.D2408H (on ENST00000219905 / NM_001164273.1; = p.D2199H on NM_001080541.2) | Missense Mutation (SNP) | VAF 44/179 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.417); catalogued as COSV99579138; called by muse, mutect2, varscan2
- MGA | c.7698G>T p.R2566S (on ENST00000219905 / NM_001164273.1; = p.R2357S on NM_001080541.2) | Missense Mutation (SNP) | VAF 20/135 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.454); catalogued as COSV54951397, COSV99579143; called by muse, mutect2, varscan2
- MGA | c.8337G>C p.K2779N (on ENST00000219905 / NM_001164273.1; = p.K2570N on NM_001080541.2) | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.276); catalogued as COSV99579147; called by muse, mutect2, varscan2
- MLLT10 | c.2045G>C p.R682P (on ENST00000307729 / NM_001195626.3; = p.R698P on NM_004641.3) | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.654); catalogued as COSV100307733; called by muse, mutect2, varscan2
- MN1 | c.2550G>C p.K850N | Missense Mutation (SNP) | VAF 24/181 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV100179722; called by muse, mutect2, varscan2
- MOB3A | c.322C>T p.R108W | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs200952352; called by muse, mutect2, varscan2
- MOGAT2 | c.302G>A p.R101Q | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT tolerated (0.34); PolyPhen benign (0.015); catalogued as rs773470557, COSV99549452; called by muse, mutect2, varscan2
- MRPS11 | c.536C>T p.T179I | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100363720; called by muse, mutect2, varscan2
- MTBP | c.206C>T p.S69L | Missense Mutation (SNP) | VAF 47/238 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.346); catalogued as COSV59961557; called by muse, mutect2, varscan2
- MYO15A | c.9875G>C p.W3292S | Missense Mutation (SNP) | VAF 57/188 reads (30%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV99231789; called by muse, mutect2, varscan2
- MYO3A | c.3817T>C p.W1273R | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); catalogued as rs1400890589, COSV99778916; called by muse, mutect2, varscan2
- NAV3 | c.5489A>T p.Q1830L (on ENST00000397909 / NM_001024383.2; = p.Q1808L on NM_014903.6) | Missense Mutation (SNP) | VAF 39/206 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.585); catalogued as COSV99888528; called by muse, mutect2, varscan2
- NCKAP5 | c.2521C>A p.P841T | Missense Mutation (SNP) | VAF 60/177 reads (34%) | SIFT tolerated (0.21); PolyPhen benign (0.158); catalogued as COSV100490842; called by muse, mutect2, varscan2
- NEDD9 | c.215C>T p.S72F | Missense Mutation (SNP) | VAF 49/126 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.429); catalogued as COSV101053384; called by muse, mutect2, varscan2
- NFE2L3 | c.2059G>C p.E687Q | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.863); catalogued as COSV99283576; called by muse, mutect2, varscan2
- NLK | c.1289G>A p.G430E | Missense Mutation (SNP) | VAF 32/178 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.972); catalogued as COSV101310964; called by muse, mutect2, varscan2
- NMBR | c.768del p.K256Nfs*45 | Frame Shift Del (DEL) | VAF 20/69 reads (29%) | catalogued as rs1470345555; called by mutect2, pindel, varscan2
- NOSTRIN | c.261-1G>C p.X87_splice (on ENST00000317647 / NM_001039724.4; = p.X9_splice on NM_052946.3) | Splice Site (SNP) | VAF 14/107 reads (13%) | catalogued as COSV100473291; called by muse, mutect2, varscan2
- NOTCH2 | c.2256C>G p.I752M | Missense Mutation (SNP) | VAF 86/299 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.039); catalogued as COSV56680211, COSV99863309; called by muse, mutect2, varscan2
- NRBF2 | c.49C>T p.R17* | Nonsense Mutation (SNP) | VAF 36/117 reads (31%) | catalogued as rs373878849, COSV53258505; called by muse, mutect2, varscan2
- NUTM1 | c.1482T>A p.S494R | Missense Mutation (SNP) | VAF 25/111 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.061); catalogued as COSV100148915; called by muse, mutect2, varscan2
- OPRM1 | c.455A>T p.N152I | Missense Mutation (SNP) | VAF 95/496 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100000842; called by muse, mutect2, varscan2
- OR2G2 | c.488C>A p.S163Y | Missense Mutation (SNP) | VAF 72/294 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV60740540; called by muse, mutect2, varscan2
- OR5F1 | c.354G>T p.M118I | Missense Mutation (SNP) | VAF 40/136 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV53549353, COSV99558485; called by muse, mutect2, varscan2
- OR5K4 | c.614C>A p.P205Q | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.752); catalogued as rs750351796, COSV100721317; called by muse, mutect2, varscan2
- PCDHA2 | c.67G>A p.A23T | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.031); catalogued as COSV100973708; called by muse, mutect2, varscan2
- PCDHA6 | c.734C>G p.S245C | Missense Mutation (SNP) | VAF 32/106 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.802); catalogued as COSV100972165, COSV100972181; called by muse, mutect2, varscan2
- PCLO | c.8452C>T p.H2818Y | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs1023966604, COSV100429470; called by muse, mutect2, varscan2
- PCLO | c.7480C>G p.P2494A | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.811); catalogued as COSV100429473; called by muse, mutect2, varscan2
- PCLO | c.7363C>G p.L2455V | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.003); catalogued as COSV100429477; called by muse, mutect2, varscan2
- PDE10A | c.2336C>G p.S779C | Missense Mutation (SNP) | VAF 26/201 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.221); catalogued as COSV100604828, COSV63093987; called by muse, mutect2, varscan2
- PDGFC | c.758G>A p.R253H | Missense Mutation (SNP) | VAF 31/257 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs769007620, COSV56845517, COSV56850924; called by muse, mutect2, varscan2
- PDZRN3 | c.1712T>A p.V571E | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.644); catalogued as COSV99728429; called by muse, mutect2, varscan2
- PHIP | c.3743C>A p.S1248Y | Missense Mutation (SNP) | VAF 32/131 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV99243679; called by muse, mutect2, varscan2
- PKD1 | c.12625G>C p.E4209Q (on ENST00000262304 / NM_001009944.3; = p.E4208Q on NM_000296.4) | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as CD1210732, COSV99237556; called by muse, mutect2, varscan2
- PKP2 | c.1005G>C p.E335D | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV99297422; called by muse, mutect2, varscan2
- PKP2 | c.469G>C p.E157Q | Missense Mutation (SNP) | VAF 86/351 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.518); catalogued as COSV99297423; called by muse, mutect2, varscan2
- PLAT | c.413C>T p.T138M | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.21); catalogued as rs759282035, COSV99535058; called by muse, mutect2, varscan2
- PLAUR | c.524G>A p.C175Y | Missense Mutation (SNP) | VAF 28/110 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99655067; called by muse, mutect2, varscan2
- PLCG2 | c.2785G>A p.E929K | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.439); catalogued as COSV63868628; called by muse, mutect2, varscan2
- PLOD1 | c.191G>T p.W64L | Missense Mutation (SNP) | VAF 60/195 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99537983; called by muse, mutect2, varscan2
- PLXNB2 | c.3736C>T p.R1246W | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100833930; called by muse, mutect2, varscan2
- PLXNB2 | c.1877+1G>A p.X626_splice | Splice Site (SNP) | VAF 23/187 reads (12%) | catalogued as COSV63782399; called by muse, mutect2, varscan2
- PMEL | c.137G>A p.R46K | Missense Mutation (SNP) | VAF 42/301 reads (14%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV62430163; called by muse, mutect2, varscan2
- POLN | c.1375G>T p.A459S | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT tolerated (0.45); PolyPhen benign (0.014); catalogued as rs1305277156, COSV101242488; called by muse, mutect2, varscan2
- POLQ | c.7379G>T p.R2460L | Missense Mutation (SNP) | VAF 83/244 reads (34%) | SIFT tolerated (0.76); PolyPhen benign (0.092); catalogued as rs183431251, COSV99951872; called by muse, mutect2, varscan2
- PPFIA2 | c.480A>T p.Q160H | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100332404; called by muse, mutect2, varscan2
- PPP1CA | c.175C>A p.L59I | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.063); catalogued as COSV100334901; called by muse, mutect2, varscan2
- PPP1R12C | c.1973C>T p.S658L | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.011); catalogued as COSV52382306; called by muse, mutect2
- PPP1R15A | c.1045G>T p.D349Y | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99565924; called by muse, mutect2, varscan2
- PSG3 | c.644A>G p.Y215C | Missense Mutation (SNP) | VAF 198/730 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100548790; called by muse, mutect2, varscan2
- RAB8B | c.202G>A p.E68K | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100368835; called by muse, mutect2, varscan2
- RAD21 | c.161G>A p.R54Q | Missense Mutation (SNP) | VAF 50/274 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1563692624, COSV52059334, COSV52064993; called by muse, mutect2, varscan2
- RAD54L | c.616G>C p.E206Q | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.588); catalogued as COSV100914771; called by muse, mutect2, varscan2
- REV3L | c.7495C>G p.R2499G | Missense Mutation (SNP) | VAF 5/90 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV100725039, COSV62617902; called by muse, mutect2
- RFC2 | c.745G>C p.E249Q (on ENST00000055077 / NM_181471.3; = p.E215Q on NM_002914.4) | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.063); catalogued as COSV99277787; called by muse, mutect2, varscan2
- RGS12 | c.2908G>C p.D970H | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100122714; called by muse, mutect2, varscan2
- RIMBP2 | c.1276G>A p.E426K | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.981); catalogued as rs889328408, COSV55471105; called by muse, mutect2, varscan2
- RIMS3 | c.655G>A p.D219N | Missense Mutation (SNP) | VAF 41/192 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.062); catalogued as COSV101013328, COSV101013552; called by muse, mutect2, varscan2
- RIN3 | c.2615C>A p.S872Y | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.149); catalogued as COSV53650005; called by muse, mutect2, varscan2
- RNF112 | c.1094G>A p.R365Q | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as rs777327708, COSV101465399, COSV99070945; called by muse, mutect2, varscan2
- RNF138 | c.488A>T p.Q163L | Missense Mutation (SNP) | VAF 29/153 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.212); catalogued as COSV99857412; called by muse, mutect2, varscan2
- RNF157 | c.727G>A p.G243R | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.578); catalogued as rs570180754, COSV53941501, COSV99486735; called by muse, mutect2, varscan2
- RNF169 | c.1343C>T p.S448L | Missense Mutation (SNP) | VAF 55/155 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV100213274; called by muse, mutect2, varscan2
- RPL7A | c.280C>G p.Q94E | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.053); catalogued as COSV100034606; called by muse, mutect2, varscan2
- RUNDC1 | c.1097C>A p.P366Q | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV100865822; called by muse, mutect2, varscan2
- SCAF8 | c.2086C>T p.P696S | Missense Mutation (SNP) | VAF 64/247 reads (26%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.981); catalogued as COSV100781297; called by muse, mutect2, varscan2
- SCAF8 | c.2887C>T p.H963Y | Missense Mutation (SNP) | VAF 140/513 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.335); catalogued as COSV65791386; called by muse, mutect2, varscan2
- SCAF8 | c.3025C>A p.Q1009K | Missense Mutation (SNP) | VAF 43/184 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.9); catalogued as COSV100914002; called by muse, mutect2, varscan2
- SCRIB | c.434G>A p.G145E | Missense Mutation (SNP) | VAF 5/92 reads (5%) | SIFT tolerated (0.4); PolyPhen probably damaging (1); catalogued as COSV100252835; called by muse, mutect2
- SEMA5A | c.1363C>T p.R455W | Missense Mutation (SNP) | VAF 46/202 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.766); catalogued as rs375389733, COSV101227486; called by muse, mutect2, varscan2
- SERAC1 | c.1538C>T p.T513M | Missense Mutation (SNP) | VAF 115/529 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.022); catalogued as rs143065058; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SERINC5 | c.1030C>T p.R344* | Nonsense Mutation (SNP) | VAF 58/154 reads (38%) | catalogued as rs185819925, COSV101549071, COSV101549138; called by muse, mutect2, varscan2
- SF3A3 | c.785G>A p.R262K | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0.285); catalogued as COSV100885619, COSV99070458; called by muse, mutect2, varscan2
- SHROOM3 | c.5577G>C p.E1859D | Missense Mutation (SNP) | VAF 19/214 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV99933868; called by muse, mutect2
- SLC1A5 | c.988C>T p.R330C | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs377758850, COSV101314760; called by mutect2, varscan2
- SLC39A4 | c.1510G>T p.D504Y (on ENST00000301305 / NM_001374839.1; = p.D479Y on NM_017767.3) | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52780435, COSV99433140; called by muse, mutect2, varscan2
- SLC9A3R2 | c.946A>G p.M316V (on ENST00000424542 / NM_001130012.3; = p.M305V on NM_004785.6) | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV99526218; called by muse, mutect2, varscan2
- SMC1A | c.2828C>T p.S943L | Missense Mutation (SNP) | VAF 7/125 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100447201; called by muse, mutect2
- SNX25 | c.90A>C p.Q30H | Missense Mutation (SNP) | VAF 45/231 reads (19%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.602); catalogued as COSV99252535; called by muse, mutect2, varscan2
- SOHLH1 | c.194G>C p.R65P | Missense Mutation (SNP) | VAF 51/153 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.689); catalogued as COSV100039992, COSV53681013; called by muse, mutect2, varscan2
- SPOCK1 | c.348-2A>G p.X116_splice | Splice Site (SNP) | VAF 19/63 reads (30%) | catalogued as COSV99968403; called by muse, mutect2, varscan2
- SPRY3 | c.563T>A p.L188H | Missense Mutation (SNP) | VAF 9/190 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100249257; called by muse, mutect2
- SPTB | c.3675G>C p.L1225F | Missense Mutation (SNP) | VAF 14/336 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.101); catalogued as COSV101072019; called by muse, mutect2
- SREK1 | c.750G>T p.K250N | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.261); catalogued as COSV99398460; called by muse, mutect2, varscan2
- STK38L | c.313C>T p.R105W | Missense Mutation (SNP) | VAF 31/141 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs774856321, COSV66523197; called by muse, mutect2, varscan2
- SUCLA2 | c.1006G>A p.D336N (on ENST00000643023; = p.D315N on NM_003850.3) | Missense Mutation (SNP) | VAF 61/169 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.168); catalogued as rs772228438, COSV66222714; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TAOK3 | c.452G>C p.G151A | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.936); catalogued as COSV101183479; called by muse, mutect2, varscan2
- TESK2 | c.1214G>A p.R405H | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1469428926, COSV59157773; called by muse, mutect2, varscan2
- TMCC1 | c.1393G>A p.E465K (on ENST00000393238 / NM_001349268.2; = p.E141K on NM_015008.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 48/208 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV100260843; called by muse, mutect2, varscan2
- TMEM106B | c.203G>A p.G68E | Missense Mutation (SNP) | VAF 23/182 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101188801; called by muse, mutect2, varscan2
- TMEM18 | c.233G>C p.R78T | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99806110; called by muse, mutect2, varscan2
- TNN | c.1809G>C p.Q603H | Missense Mutation (SNP) | VAF 27/116 reads (23%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.764); catalogued as COSV53422266, COSV99511469; called by muse, mutect2, varscan2
- TNRC6C | c.994A>C p.S332R | Missense Mutation (SNP) | VAF 31/144 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.08); catalogued as COSV100049662; called by muse, mutect2, varscan2
- TPO | c.1465G>A p.A489T | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755919271, COSV61108700; called by muse, mutect2, varscan2
- TRBV24-1 | c.152T>C p.M51T | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as rs543314925; called by muse, mutect2, varscan2
- TRPC1 | c.1236G>C p.K412N (on ENST00000476941 / NM_001251845.2; = p.K378N on NM_003304.4) | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.966); catalogued as COSV99858440; called by muse, mutect2, varscan2
- TSC2 | c.5393C>G p.S1798C | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV51925109, COSV99237554; called by muse, mutect2, varscan2
- TSGA10 | c.98G>C p.R33P | Missense Mutation (SNP) | VAF 31/106 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as COSV100747476, COSV61824046; called by muse, mutect2, varscan2
- TTN | c.56633G>T p.R18878L (on ENST00000591111; = p.R11454L on NM_003319.4) | Missense Mutation (SNP) | VAF 43/192 reads (22%) | PolyPhen benign (0.025); catalogued as COSV100601567; called by muse, mutect2, varscan2
- UCKL1 | c.843A>G p.R281= | Splice Region (SNP) | VAF 3/21 reads (14%) | catalogued as COSV100700472; called by muse, mutect2
- UGT1A4 | c.497C>T p.S166L | Missense Mutation (SNP) | VAF 75/303 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.511); catalogued as rs149079663, COSV100530601; called by muse, mutect2, varscan2
- USH2A | c.1078A>T p.T360S | Missense Mutation (SNP) | VAF 61/202 reads (30%) | SIFT tolerated (0.5); PolyPhen benign (0.061); catalogued as COSV100231770; called by muse, mutect2, varscan2
- VPS16 | c.2359G>A p.A787T | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.903); catalogued as rs767906066, COSV100988359; called by muse, mutect2, varscan2
- VPS50 | c.991G>T p.A331S | Missense Mutation (SNP) | VAF 25/128 reads (20%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.548); catalogued as COSV100004643; called by muse, mutect2, varscan2
- WDR25 | c.518T>A p.V173E | Missense Mutation (SNP) | VAF 50/151 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.169); catalogued as COSV100091533; called by muse, mutect2, varscan2
- ZBED6CL | c.259G>A p.A87T | Missense Mutation (SNP) | VAF 8/152 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.05); catalogued as COSV100550407; called by muse, mutect2
- ZFYVE28 | c.1541C>T p.S514L | Missense Mutation (SNP) | VAF 18/118 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV99342611; called by muse, mutect2, varscan2
- ZGPAT | c.232G>C p.E78Q | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV100157501; called by muse, mutect2, varscan2
- ZKSCAN5 | c.1870C>G p.Q624E | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.555); catalogued as COSV100460067; called by muse, mutect2, varscan2
- ZKSCAN5 | c.2482C>T p.P828S | Missense Mutation (SNP) | VAF 85/285 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV58741869; called by muse, mutect2, varscan2
- ZNF207 | c.667C>G p.Q223E | Missense Mutation (SNP) | VAF 44/160 reads (28%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.83); catalogued as COSV58300796; called by muse, mutect2, varscan2
- ZNF217 | c.865C>T p.Q289* | Nonsense Mutation (SNP) | VAF 54/165 reads (33%) | catalogued as COSV56596721; called by muse, mutect2, varscan2
- ZNF354B | c.105G>C p.Q35H | Missense Mutation (SNP) | VAF 42/175 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100482936; called by muse, mutect2, varscan2
- ZNF444 | c.355C>A p.Q119K | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV100442520; called by muse, mutect2, varscan2
- ZNF461 | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 36/154 reads (23%) | SIFT tolerated (0.89); PolyPhen benign (0.031); catalogued as COSV100831379, COSV64453641; called by muse, mutect2, varscan2
- ZNF626 | c.818G>C p.S273T | Missense Mutation (SNP) | VAF 32/170 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV101656962; called by muse, mutect2, varscan2
- ZNF675 | c.1245G>C p.K415N | Missense Mutation (SNP) | VAF 42/178 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.733); catalogued as COSV100704975; called by muse, mutect2, varscan2
- ZSCAN30 | c.373G>C p.E125Q | Missense Mutation (SNP) | VAF 21/110 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV100310097; called by muse, mutect2, varscan2
- DMRTA2 | c.947del p.P316Rfs*5 | Frame Shift Del (DEL) | VAF 16/76 reads (21%) | called by mutect2, pindel, varscan2
- MNDA | c.476dup p.G160Rfs*65 | Frame Shift Ins (INS) | VAF 69/313 reads (22%) | called by mutect2, pindel, varscan2
- MPDZ | c.3877_3882delinsTT p.P1293Ffs*51 | Frame Shift Del (DEL) | VAF 39/207 reads (19%) | called by pindel, varscan2*
- NMNAT1 | c.288del p.K97Rfs*3 | Frame Shift Del (DEL) | VAF 52/220 reads (24%) | called by mutect2, pindel, varscan2
- SCN9A | c.2033del p.D678Vfs*3 (on ENST00000303354; = p.D667Vfs*3 on NM_002977.3) | Frame Shift Del (DEL) | VAF 29/185 reads (16%) | called by mutect2, pindel, varscan2
- TP53 | c.200_216del p.P67Rfs*76 | Frame Shift Del (DEL) | VAF 55/226 reads (24%) | called by mutect2, pindel, varscan2
- TRAF2 | c.1448_1457del p.S483Wfs*13 | Frame Shift Del (DEL) | VAF 20/80 reads (25%) | called by mutect2, pindel, varscan2
- ABCC9 | c.1344C>G p.L448= | Silent (SNP) | VAF 26/120 reads (22%) | catalogued as COSV99685072; called by muse, mutect2, varscan2
- ADGRB3 | c.474G>A p.L158= | Silent (SNP) | VAF 33/167 reads (20%) | catalogued as COSV101000239; called by muse, mutect2, varscan2
- APOH | c.144G>T p.T48= | Silent (SNP) | VAF 58/271 reads (21%) | catalogued as COSV52771958, COSV99235642; called by muse, mutect2, varscan2
- ARHGAP1 | c.381C>T p.H127= | Silent (SNP) | VAF 51/210 reads (24%) | catalogued as rs564406586, COSV100357850; called by muse, mutect2, varscan2
- ASIC3 | c.351G>A p.L117= | Silent (SNP) | VAF 15/66 reads (23%) | catalogued as COSV99874073; called by muse, mutect2, varscan2
- ATP13A4 | c.3312C>T p.P1104= | Silent (SNP) | VAF 12/111 reads (11%) | catalogued as rs766687694, COSV100710204; called by muse, mutect2, varscan2
- BTBD3 | c.783C>T p.F261= | Silent (SNP) | VAF 36/146 reads (25%) | catalogued as COSV54781616; called by muse, mutect2, varscan2
- CACNA2D4 | c.894G>C p.V298= | Silent (SNP) | VAF 18/74 reads (24%) | catalogued as COSV99765325; called by muse, mutect2, varscan2
- CAMKK1 | c.327C>T p.I109= | Silent (SNP) | VAF 9/20 reads (45%) | catalogued as COSV99340103; called by muse, mutect2, varscan2
- CASZ1 | c.2379G>A p.S793= | Silent (SNP) | VAF 5/50 reads (10%) | catalogued as rs750085734, COSV100680997; called by muse, mutect2
- CBX4 | c.900C>T p.D300= | Silent (SNP) | VAF 33/133 reads (25%) | catalogued as rs758891335, COSV53964942; called by muse, varscan2
- CCDC134 | c.210C>G p.L70= | Silent (SNP) | VAF 14/79 reads (18%) | catalogued as COSV99740585; called by muse, mutect2, varscan2
- CCDC134 | c.486C>G p.L162= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as COSV99740586; called by muse, mutect2
- CELA3A | c.780C>T p.I260= | Silent (SNP) | VAF 17/103 reads (17%) | catalogued as rs144074674; called by muse, mutect2
- CNTNAP5 | c.2871C>T p.P957= | Silent (SNP) | VAF 11/83 reads (13%) | catalogued as rs745860435, COSV70484294; called by muse, mutect2, varscan2
- COL28A1 | c.1290C>T p.I430= | Silent (SNP) | VAF 54/210 reads (26%) | catalogued as COSV101258427; called by muse, mutect2, varscan2
- COL6A3 | c.2343G>A p.A781= | Silent (SNP) | VAF 13/47 reads (28%) | catalogued as rs561804945, COSV99796915; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- CORO2A | c.1572G>A p.Q524= | Silent (SNP) | VAF 10/24 reads (42%) | catalogued as rs769534600, COSV100673994; called by muse, mutect2, varscan2
- CREB5 | c.1194C>T p.V398= (on ENST00000357727 / NM_182898.4; = p.V391= on NM_004904.3) | Silent (SNP) | VAF 13/89 reads (15%) | catalogued as COSV100744385; called by muse, mutect2, varscan2
- CST7 | c.42C>G p.V14= | Silent (SNP) | VAF 17/84 reads (20%) | catalogued as COSV100961928; called by muse, mutect2, varscan2
- EDC4 | c.1263G>C p.L421= | Silent (SNP) | VAF 84/233 reads (36%) | catalogued as COSV100738984; called by muse, mutect2, varscan2
- EFEMP2 | c.375C>T p.D125= | Silent (SNP) | VAF 9/62 reads (15%) | catalogued as rs758495680, COSV100337204; ClinVar: likely benign; called by muse, mutect2, varscan2
- ELL | c.588G>A p.V196= | Silent (SNP) | VAF 23/102 reads (23%) | catalogued as rs779523781, COSV99442929; called by muse, mutect2, varscan2
- ETV5 | c.123C>T p.H41= | Silent (SNP) | VAF 40/204 reads (20%) | catalogued as rs529743588, COSV100112054; called by muse, mutect2, varscan2
- FRK | c.594C>T p.D198= | Silent (SNP) | VAF 79/414 reads (19%) | catalogued as rs773491750, COSV101606639; called by muse, mutect2, varscan2
- GRID1 | c.2211C>T p.Y737= | Silent (SNP) | VAF 25/63 reads (40%) | catalogued as rs759438284, COSV60021998; called by muse, mutect2, varscan2
- GRIN1 | c.1194G>T p.L398= | Silent (SNP) | VAF 47/127 reads (37%) | catalogued as COSV100160024; called by muse, mutect2, varscan2
- HOXB3 | c.525C>A p.G175= | Silent (SNP) | VAF 16/61 reads (26%) | catalogued as COSV100290594; called by muse, mutect2, varscan2
- HSPA8 | c.1494G>A p.E498= | Silent (SNP) | VAF 13/213 reads (6%) | catalogued as rs1387335670, COSV99914216, COSV99914285; called by muse, mutect2
- IPO7 | c.315C>T p.L105= | Silent (SNP) | VAF 14/182 reads (8%) | catalogued as COSV101121801; called by muse, mutect2
- ITK | c.546C>T p.Y182= | Silent (SNP) | VAF 28/118 reads (24%) | catalogued as COSV101439670; called by muse, mutect2, varscan2
- JAK3 | c.3039C>T p.F1013= | Silent (SNP) | VAF 23/73 reads (32%) | catalogued as COSV101512899; called by muse, mutect2, varscan2
- KCNT2 | c.1722G>T p.V574= | Silent (SNP) | VAF 35/242 reads (14%) | catalogued as COSV99652485; called by muse, mutect2, varscan2
- LDLRAD2 | c.171C>T p.F57= | Silent (SNP) | VAF 8/64 reads (13%) | catalogued as COSV100760737; called by muse, mutect2, varscan2
- MGA | c.7596G>A p.K2532= (on ENST00000219905 / NM_001164273.1; = p.K2323= on NM_001080541.2) | Silent (SNP) | VAF 15/68 reads (22%) | catalogued as COSV54953328, COSV54953834; called by muse, mutect2, varscan2
- MMP3 | c.1053C>T p.L351= | Silent (SNP) | VAF 42/148 reads (28%) | catalogued as rs782345550, COSV55407748; called by muse, mutect2, varscan2
- MUC17 | c.5448C>T p.S1816= | Silent (SNP) | VAF 62/468 reads (13%) | catalogued as rs1471192307, COSV60303739; called by muse, mutect2, varscan2
- MYH6 | c.3852C>T p.T1284= | Silent (SNP) | VAF 33/88 reads (38%) | catalogued as rs141143152; ClinVar: likely benign; called by muse, mutect2, varscan2
- NAGLU | c.1191C>T p.F397= | Silent (SNP) | VAF 36/156 reads (23%) | catalogued as COSV99864038; called by muse, mutect2, varscan2
- NAGS | c.51G>A p.P17= | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as rs1009436443, COSV53227809; called by muse, mutect2, varscan2
- NOS2 | c.2442C>T p.V814= | Silent (SNP) | VAF 11/42 reads (26%) | catalogued as COSV100569552; called by muse, mutect2, varscan2
- NPEPPS | c.1150C>T p.L384= | Silent (SNP) | VAF 7/26 reads (27%) | called by mutect2, varscan2
- OBSL1 | c.90G>A p.E30= | Silent (SNP) | VAF 8/16 reads (50%) | catalogued as COSV99216498; called by muse, varscan2
- OPRD1 | c.615C>A p.P205= | Silent (SNP) | VAF 18/92 reads (20%) | catalogued as COSV99330148; called by muse, mutect2, varscan2
- PAMR1 | c.159C>T p.C53= | Silent (SNP) | VAF 25/168 reads (15%) | catalogued as rs1162976422, COSV53512371; called by muse, mutect2, varscan2
- PC | c.630C>T p.Y210= | Silent (SNP) | VAF 10/118 reads (8%) | catalogued as rs751914905, COSV100852115; called by muse, mutect2
- PEG3 | c.1944C>T p.I648= | Silent (SNP) | VAF 38/159 reads (24%) | catalogued as COSV99688021; called by muse, mutect2, varscan2
- PHTF1 | c.1071T>C p.G357= | Silent (SNP) | VAF 11/74 reads (15%) | catalogued as COSV100760042; called by muse, mutect2, varscan2
- PKHD1 | c.2982G>A p.R994= | Silent (SNP) | VAF 31/181 reads (17%) | catalogued as COSV100582078; called by muse, mutect2, varscan2
- PTOV1 | c.660C>T p.Y220= | Silent (SNP) | VAF 96/455 reads (21%) | catalogued as rs199546041; called by muse, mutect2, varscan2
- PTPRJ | c.2658C>T p.L886= | Silent (SNP) | VAF 29/106 reads (27%) | catalogued as COSV101394724; called by muse, mutect2, varscan2
- QRICH2 | c.4575C>T p.R1525= | Silent (SNP) | VAF 38/146 reads (26%) | catalogued as rs1200545509, COSV99428942; called by muse, mutect2, varscan2
- RGS5 | c.168C>T p.D56= | Silent (SNP) | VAF 34/115 reads (30%) | catalogued as rs777324995, COSV58351733; called by muse, mutect2, varscan2
- RINT1 | c.1458C>G p.L486= | Silent (SNP) | VAF 38/144 reads (26%) | catalogued as rs544265915, COSV57559710, COSV99994291; ClinVar: likely benign; called by muse, mutect2, varscan2
- SEC24B | c.2949A>G p.L983= | Silent (SNP) | VAF 11/96 reads (11%) | catalogued as COSV99493106; called by muse, mutect2, varscan2
- SEPTIN5 | c.555G>T p.V185= | Silent (SNP) | VAF 14/70 reads (20%) | catalogued as COSV100820383; called by muse, mutect2, varscan2
- SETBP1 | c.4218C>T p.A1406= | Silent (SNP) | VAF 12/93 reads (13%) | catalogued as COSV99952544; called by muse, mutect2, varscan2
- SHLD2 | c.1557C>T p.G519= | Silent (SNP) | VAF 10/66 reads (15%) | catalogued as rs3129495, COSV100079015; called by muse, mutect2
- SLC6A8 | c.1578C>T p.F526= | Silent (SNP) | VAF 36/87 reads (41%) | catalogued as COSV99465823; called by muse, mutect2, varscan2
- SOX17 | c.1244G>A p.*415= | Silent (SNP) | VAF 26/109 reads (24%) | catalogued as COSV52027815; called by muse, mutect2, varscan2
- SRCIN1 | c.1704G>A p.S568= (on ENST00000621492; = p.S534= on NM_025248.3) | Silent (SNP) | VAF 8/35 reads (23%) | called by mutect2, varscan2
- TAS2R60 | c.696A>T p.S232= | Silent (SNP) | VAF 21/109 reads (19%) | catalogued as COSV100223491; called by muse, mutect2, varscan2
- TAX1BP1 | c.2196C>T p.L732= | Silent (SNP) | VAF 22/156 reads (14%) | catalogued as rs367746678; called by muse, mutect2, varscan2
- TLE5 | c.135C>T p.L45= | Silent (SNP) | VAF 19/68 reads (28%) | catalogued as rs139924030; called by muse, mutect2, varscan2
- TMEM143 | c.912C>G p.L304= | Silent (SNP) | VAF 13/69 reads (19%) | catalogued as COSV53158507, COSV99507060; called by muse, mutect2, varscan2
- TTC21A | c.1281G>A p.A427= | Silent (SNP) | VAF 7/103 reads (7%) | catalogued as rs1488299447, COSV100087140; called by muse, mutect2
- ZBTB32 | c.435T>C p.P145= | Silent (SNP) | VAF 14/65 reads (22%) | catalogued as COSV99385927; called by muse, mutect2, varscan2
- ZDBF2 | c.3576T>C p.N1192= | Silent (SNP) | VAF 25/186 reads (13%) | catalogued as COSV100984513; called by muse, mutect2, varscan2
- ZIM3 | c.1368C>T p.F456= | Silent (SNP) | VAF 64/238 reads (27%) | catalogued as COSV54139507, COSV99518166; called by muse, mutect2, varscan2
- ZNF646 | c.1248C>T p.L416= | Silent (SNP) | VAF 14/32 reads (44%) | catalogued as COSV100336505; called by muse, mutect2, varscan2
- ZNF76 | c.1407C>T p.L469= | Silent (SNP) | VAF 27/130 reads (21%) | catalogued as rs780385407, COSV99987582; called by muse, mutect2, varscan2
- ZNRF3 | c.1179C>T p.P393= (on ENST00000544604 / NM_001206998.2; = p.P293= on NM_032173.3) | Silent (SNP) | VAF 11/82 reads (13%) | catalogued as rs1438566404, COSV100238135; called by muse, mutect2, varscan2
- OBSCN | c.5138-1719A>C | Intron (SNP) | VAF 26/98 reads (27%) | catalogued as COSV99475330; called by muse, mutect2, varscan2
- OR3A4P | n.1190A>T | RNA (SNP) | VAF 7/155 reads (5%) | called by muse, mutect2
- TECR | chr19:14529560 G>A | 5'Flank (SNP) | VAF 4/9 reads (44%) | catalogued as rs745620953; called by muse, varscan2
- TMEM107 | c.156-11C>T | Intron (SNP) | VAF 41/125 reads (33%) | catalogued as COSV100328698; called by muse, mutect2, varscan2
